FM case AD451 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/a0243691-4833-4b4a-b144-8147bc8c172f

Male, 56.9 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; primary biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
